Gene-level copy-number profile of tumor specimen TCGA-23-1030-01A from TCGA case TCGA-23-1030, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.1 years (23,416 days).
Specimen TCGA-23-1030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.674cc1fd-0abf-4b98-97a0-ef3870382296.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1030-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a008d120-4f1d-4a42-a6e7-c77b8eae11fb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,938; copy number 2: 22,252; copy number 3: 27,287; copy number 4: 4,045; copy number 5: 3,573; copy number 6: 411; copy number 7: 148; copy number 9: 147; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1030-01A-02D-0428-01): tumor purity 0.87, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 298 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:183,248,237–183,418,380, 3 genes, copy number 10 (within-gene range 6–10): NMNAT2, AL354953.1, RPS3AP8.
- chr11:119,709,920–120,028,341, 9 genes, copy number 7: NECTIN1-AS1, AP003390.1, AP001994.1, AP001994.2, AP001994.3, AP001360.3, LINC02744, AP001360.1, AP001360.2.
- chr17:74,417,594–75,708,062, 71 genes, copy number 7 (broad region; genes not listed).
- chr19:13,731,760–16,245,906, 147 genes, copy number 9 (broad region; genes not listed).
- chr20:3,043,622–5,197,887, 68 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
